TCGA case TCGA-IB-7645 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7a1d9862-910b-403e-9eab-697dc65618c7

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 44 years; Vital status: Dead; Days to death: 1,502 days (4.1 years); Cause of death: Cancer Related; Cause of death source: Death Certificate.

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 44.2 years (16,126 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,502 days (4.1 years); Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 5; Lymph nodes tested: 17; Tumor largest dimension diameter: 4.5 cm.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Fluorouracil; Days to treatment start: 38 days; Days to treatment end: 178 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin; Days to treatment start: 38 days; Days to treatment end: 178 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 811 days (2.2 years); Days to treatment end: 1,230 days (3.4 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Gemcitabine Hydrochloride; Days to treatment start: 1,224 days (3.4 years); Days to treatment end: 1,230 days (3.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Oxaliplatin; Days to treatment start: 1,309 days (3.6 years); Days to treatment end: 1,377 days (3.8 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 1,309 days (3.6 years); Days to treatment end: 1,377 days (3.8 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Liver. Age at diagnosis: 46.8 years (17,110 days); Days to diagnosis: 984 days (2.7 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 47.5 years (17,336 days); Days to diagnosis: 1,210 days (3.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Day 984 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 984 days (2.7 years).
- Day 1,210 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,210 days (3.3 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 1,502 days (4.1 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IB-7645-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1.4; Shortest dimension: 0.3.
  Slide TCGA-IB-7645-01A-01-BS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 40; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 10.
- Sample TCGA-IB-7645-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IB-7645-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tumor status: With tumor; Cause of death: Pancreatic Cancer; Tobacco smoking history indicator: 1; Diabetes diagnosis indicator: No; History chronic pancreatitis: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Cause of death: Pancreatic Cancer.
- Drug treatment 1: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Drug treatment 3: Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Pharmaceutical therapy drug name: 5-Fluorouracil; Treatment best response: Clinical Progressive Disease.
- Drug treatment 8: Pharmaceutical therapy drug name: Gemzar; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,502 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,502 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 984 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IB-7645-01A-22D-2200-01): tumor purity 1, ploidy 2, whole-genome doublings 0.
